Somatic mutation profile of tumor specimen 0DLHOW from CCDI case PBBYHL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (429 days).
Specimen 0DLHOW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc4d287a-44d8-4a33-8587-29722ae6274a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3e17bd1-1254-44bc-ac89-ce1d0e71c2d2

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/914 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- SOWAHD | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF534 | c.1867G>A p.E623K (on ENST00000332323 / NM_001143939.3; = p.E610K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/531 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.39); called by muse, mutect2
- KLHL23 | c.681C>T p.N227= | Silent (SNP) | VAF 25/771 reads (3%) | called by muse, mutect2
